Gene-level copy-number profile of tumor specimen TARGET-40-PALWWX-01A from TARGET case TARGET-40-PALWWX, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.2 years (4,464 days).
Specimen TARGET-40-PALWWX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.129a4ab8-6d3b-5290-8820-c4df310a21ba.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PALWWX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 405 have no estimate.
https://portal.gdc.cancer.gov/files/268baf45-921f-4c2a-a6b3-75a822f02f5f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 493; copy number 2: 19,849; copy number 3: 18,225; copy number 4: 16,689; copy number 5: 2,241; copy number 6: 1,628; copy number 7: 463; copy number 8: 100; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,965,227, 4 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr13:48,232,612–48,303,661, 2 genes: ITM2B, RB1-DT.
- chr13:48,316,863–48,341,330, 3 genes: PPP1R26P1, PCNPP5, AL392048.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 564 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,628,899, 5 genes, copy number 8: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3.
- chr5:52,930,606–52,990,278, 1 gene, copy number 9 (within-gene range 5–9): AC025180.1.
- chr7:10,702,676–21,945,903, 122 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:66,767–9,658,392, 347 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:9,695,384–11,895,377, 89 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 493. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
